Surgical pathology report (de-identified scan), TCGA case TCGA-IG-A3I8, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Asterand, specimen TCGA-IG-A3I8-01A (Primary Tumor).

Procurement Date: Laterality:

Path Report: ESOPHAGUS TISSUE CHECKLIST

Specimen type: Excision of tumor

Tumor site: Esophagus

Tumor size: 3.5 x 3 x 1.5 cm

Histologic type: Squamous cell carcinoma, keratinizing

Histologic grade: Moderately differentiated

Tumor extent: Adventitia

Lymph nodes: 0/5 positive for metastasis (Regional 0/5)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Involved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

ICD-0-3

Gross Description:

carcinoma, squamous cell. Keratinizing, NOS
8071/3

Microscopic Description:

Path Site: esophagus, NOS c15.9

Diagnosis Details:

CQCF Site: esophagus, distal third
c15.5

12/1/11

Census (circle) QUALIFIED		
Revised/Updated: 12/1/11		

Source: NCI Genomic Data Commons file c328040f-1c08-4679-b022-73473e7cf101 (TCGA-IG-A3I8.713A7788-1D77-4810-96FD-7E803185A1D9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).